MMRF case MMRF_1267 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f65c5bfa-cf3b-4c03-a4b4-47c8d935960b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 39 years; Vital status: Dead; Days to death: 1,147 days (3.1 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 39.8 years (14,542 days); ISS stage: II; Days to last known disease status: 1,147 days (3.1 years); Days to last follow up: 1,147 days (3.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 183 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 183 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 191 days; Days to treatment end: 224 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 234 days; Days to treatment end: 234 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 235 days; Days to treatment end: 235 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 368 days (1.0 years); Days to treatment end: 368 days (1.0 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 371 days (1.0 years); Days to treatment end: 371 days (1.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 472 days (1.3 years); Days to treatment end: 665 days (1.8 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 472 days (1.3 years); Days to treatment end: 1,066 days (2.9 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 472 days (1.3 years); Days to treatment end: 563 days (1.5 years).
   Treatment given: Therapeutic agents: Bendamustine; Regimen or line of therapy: Third line of therapy; Days to treatment start: 901 days (2.5 years); Days to treatment end: 901 days (2.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 901 days (2.5 years); Days to treatment end: 945 days (2.6 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 901 days (2.5 years); Days to treatment end: 924 days (2.5 years).
   Treatment given: Therapeutic agents: Carmustine; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 945 days (2.6 years); Days to treatment end: 963 days (2.6 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 960 days (2.6 years); Days to treatment end: 960 days (2.6 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 962 days (2.6 years); Days to treatment end: 962 days (2.6 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 985 days (2.7 years); Days to treatment end: 1,016 days (2.8 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 1,010 days (2.8 years); Days to treatment end: 1,016 days (2.8 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 1,036 days (2.8 years); Days to treatment end: 1,066 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Doxorubicin + Other + Thalidomide; Regimen or line of therapy: Seventh line of therapy; Days to treatment start: 1,066 days (2.9 years); Days to treatment end: 1,094 days (3.0 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,147.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 5.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.038 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 35.2 mg/dL; Immunoglobulin G 73.3 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 1.53 µg/mL; Lactate Dehydrogenase 5.12 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 30 g/L; Total Protein 11.7 g/dL; Glucose 5.06 mmol/L.
- Day 84 (ECOG 1): M Protein 0.54 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.1 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 5.12 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 5.39 mmol/L.
- Day 183 (ECOG 1): M Protein 1.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.456 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.91 mg/dL; Immunoglobulin G 19.8 g/L; Immunoglobulin A 1.17 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 1.34 µg/mL; Lactate Dehydrogenase 4.45 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 263 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 7.2 g/dL; Glucose 7.43 mmol/L.
- Day 343 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.669 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 9.84 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.68 g/L; Beta 2 Microglobulin 1.35 µg/mL; Lactate Dehydrogenase 4.17 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 4.9 mmol/L.
- Day 465 (ECOG 0): M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.602 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 9.72 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.65 µg/mL; Lactate Dehydrogenase 4.22 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 4.95 mmol/L.
- Day 576 (ECOG 0): M Protein 1.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.056 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.1 mg/dL; Immunoglobulin G 22.9 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.51 g/L; Beta 2 Microglobulin 1.61 µg/mL; Lactate Dehydrogenase 4.43 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.43 mmol/L; Albumin 38 g/L; Total Protein 8.3 g/dL; Glucose 6.22 mmol/L.
- Day 996 (ECOG 1): M Protein 1.92 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 30.8 mg/dL; Immunoglobulin G 26.4 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 1.54 g/L; Beta 2 Microglobulin 4.06 µg/mL; Lactate Dehydrogenase 5.27 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 5.15 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 29 g/L; Total Protein 7.1 g/dL; Glucose 6.22 mmol/L.
- Day 1,080 (ECOG 0): M Protein 2.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.046 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 50.8 mg/dL; Immunoglobulin G 20.9 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 5.55 µg/mL; Lactate Dehydrogenase 27.8 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 18 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 19.3 mmol/L; Calcium 1.83 mmol/L; Albumin 24 g/L; Total Protein 6.1 g/dL; Glucose 5.23 mmol/L.

Other clinical attributes
- Day 0: Weight: 148 kg; Height: 186 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1267_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1267_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
